Somatic mutation profile of tumor specimen MP2PRT-PAWBRA-TMP1-A (aliquot MP2PRT-PAWBRA-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAWBRA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,169 days).
Specimen MP2PRT-PAWBRA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 932fd088-2927-472f-9c1c-2d930b4477d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWBRA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWBRA-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc467a8b-cf15-4adc-8a32-1df67a94b30b

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Splice Region 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 28/439 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758467730; called by muse, mutect2
- LRP1B | c.7732G>A p.G2578R | Missense Mutation (SNP) | VAF 111/308 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766923818, COSV101253669; called by muse, mutect2, varscan2
- NR5A1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 118/588 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs104894118, CM003021, COSV65295395; called by muse, varscan2
- PTCH1 | c.3490G>A p.V1164I | Missense Mutation (SNP) | VAF 120/413 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as rs371346118, COSV59462005, COSV59466119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMELX | c.571-1G>T p.X191_splice | Splice Site (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- PPP4R1 | c.2412G>A p.L804= (on ENST00000400556 / NM_001042388.3; = p.L787= on NM_005134.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 28/255 reads (11%) | called by muse, mutect2
- GRIN3B | c.1584G>A p.A528= | Silent (SNP) | VAF 39/615 reads (6%) | catalogued as rs62131161; called by muse, mutect2
